Gene-level copy-number profile of tumor specimen TCGA-06-0148-01A from TCGA case TCGA-06-0148, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 76.2 years (27,842 days).
Specimen TCGA-06-0148-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.903204e6-6c57-4f7e-8b3c-fc3f43074b7b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0148-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3d021785-4338-4505-bad9-138a250ca195

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 133; copy number 1: 4,920; copy number 2: 47,204; copy number 3: 7,496; copy number 4: 34; copy number 22: 23; copy number 25: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-06-0148-01): tumor purity 1, ploidy 2.03, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 133 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:452,492–746,106, 6 genes (within-gene range 0–1): AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P.
- chr9:20,331,446–29,826,711, 127 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 28 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,933,699–55,255,635, 5 genes, copy number 25 (within-gene range 3–25): AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1.
- chr14:104,474,678–104,978,374, 23 genes, copy number 22 (within-gene range 2–22): TMEM179, C14orf180, BX927359.1, AL583722.2, LINC02280, MIR4710, INF2, AL583722.3, ADSS1, SIVA1, AL583722.1, AKT1, ZBTB42, AL590326.1, LINC00638, RPS26P49, RPS2P4, AL583810.2, AL583810.1, CEP170B, AL583810.3, PLD4, AHNAK2.

Autosomal genes at a single copy (total copy number 1): 2,533. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
